Somatic mutation profile of tumor specimen TCGA-DX-A2J1-01A (aliquot TCGA-DX-A2J1-01A-11D-A21Q-09) from TCGA case TCGA-DX-A2J1, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 54.0 years (19,707 days).
Specimen TCGA-DX-A2J1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5b6fb010-fee3-4d27-a5da-4fcd616bd734.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-A2J1-10A (Blood Derived Normal), aliquot TCGA-DX-A2J1-10A-01D-A21Q-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fd241ea9-d440-49a9-8fe7-ccba3d7e6786

The open-access MAF lists 26 somatic variants for this specimen: 20 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 5, Nonsense Mutation 2, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 11/50 reads (22%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BIRC2 | c.1129C>T p.H377Y | Missense Mutation (SNP) | VAF 30/698 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.019); catalogued as COSV57162350; called by muse, mutect2
- CTTN | c.190C>T p.Q64* | Nonsense Mutation (SNP) | VAF 15/88 reads (17%) | catalogued as COSV100097834; called by muse, mutect2, varscan2
- DLGAP1 | c.754C>T p.R252W | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs572784569, COSV100231755; called by muse, mutect2, varscan2
- DUSP21 | c.394G>A p.A132T | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs752238632, COSV100173569; called by muse, mutect2, varscan2
- E2F7 | c.6G>C p.E2D | Missense Mutation (SNP) | VAF 76/111 reads (68%) | SIFT tolerated (0.05); PolyPhen benign (0.026); catalogued as COSV100523573; called by muse, mutect2, varscan2
- EDEM3 | c.1631G>T p.S544I | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as COSV100545405; called by mutect2, varscan2
- EPHA5 | c.1085G>A p.R362Q | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0.024); catalogued as rs763166233, COSV99899455; called by muse, mutect2, varscan2
- GOLGA6L9 | c.1005C>A p.N335K | Missense Mutation (SNP) | VAF 39/158 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.133); catalogued as rs1296238008; called by muse, mutect2, varscan2
- GRIA1 | c.1134G>A p.K378= | Splice Region (SNP) | VAF 7/36 reads (19%) | catalogued as rs1299953702, COSV99600502; called by muse, mutect2, varscan2
- IL17RA | c.311C>T p.A104V | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.721); catalogued as COSV100083206; called by muse, mutect2, varscan2
- KCNH4 | c.1406T>C p.V469A | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.122); catalogued as COSV99237362; called by muse, mutect2, varscan2
- KCNH8 | c.2974G>C p.D992H | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV100110106; called by muse, mutect2, varscan2
- KCNJ6 | c.773C>T p.T258M | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.17); PolyPhen probably damaging (1); catalogued as rs1273885204, COSV55711643, COSV55724768; called by muse, mutect2, varscan2
- KIF26A | c.1141G>T p.A381S | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs769390689, COSV100181234, COSV59466720; called by muse, mutect2, varscan2
- MUC17 | c.8212G>T p.G2738C | Missense Mutation (SNP) | VAF 18/157 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as COSV100073779, COSV60306377; called by muse, mutect2, varscan2
- PPP1R1A | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 248/285 reads (87%) | SIFT tolerated (0.05); PolyPhen benign (0.329); catalogued as COSV99226412; called by muse, mutect2, varscan2
- PPP1R1A | c.333G>C p.Q111H | Missense Mutation (SNP) | VAF 250/288 reads (87%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.952); catalogued as COSV99226414; called by muse, mutect2, varscan2
- SLC4A8 | c.1293C>G p.H431Q | Missense Mutation (SNP) | VAF 110/422 reads (26%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV100177055; called by muse, mutect2, varscan2
- SLC9C2 | c.2884G>A p.V962I | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs147401558, COSV100876785, COSV62944215; called by muse, mutect2, varscan2
- FAT2 | c.12447G>A p.P4149= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as rs758682292, COSV99943238; called by muse, mutect2
- FBXW10 | c.1497T>G p.T499= | Silent (SNP) | VAF 9/63 reads (14%) | catalogued as COSV100111511; called by muse, mutect2, varscan2
- GIMAP8 | c.1677C>T p.Y559= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV56231721; called by muse, mutect2, varscan2
- SLC31A2 | c.186C>T p.I62= | Silent (SNP) | VAF 598/629 reads (95%) | catalogued as COSV99406930; called by muse, varscan2
- ZNF229 | c.573G>A p.A191= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as rs752878423, COSV52166171; called by mutect2, varscan2
- ELAVL2 | c.-12-2784G>A | Intron (SNP) | VAF 6/24 reads (25%) | catalogued as COSV99806430; called by muse, mutect2
